CCDI case PBCGPB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e8ba4938-4feb-4247-beb7-ae69b067e561

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.8 years (284 days).

Biospecimens (4 samples)
- Sample 0DRPJ9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DS10A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Samples 0DSEKG, 0DSEL0 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
